Surgical pathology report (de-identified scan), TCGA case TCGA-14-1821, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1821-01A (Primary Tumor).

[page 1 of 3]
AP Report

* Final Report *

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: AP REPORT
Encounter info:

TCGA-14-1821

* Final Report *

AP REPORT

Patient: Accession Number:
Patient Number: Date Collected:
Financial Number: Date Received:
Room/Bed: PT:
Admitting Physician:
Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, RIGHT FRONTAL, BIOPSY, FS1A, TP1A:
- GLIOBLASTOMA MULTIFORME, SMALL CELL PATTERN.
- SEE COMMENT.
2. BRAIN, RIGHT FRONTAL, EXCISION:
- GLIOBLASTOMA MULTIFORME, SMALL CELL PATTERN.
- SEE COMMENT.

COMMENT:

This malignant small cell tumor discloses patchy strong staining for GFAP and a high MIB-1 proliferative rate estimated at 25-30%. Immunostains for neurofilament and synaptophysin disclose entrapped ganglion cells and axons with only questionable staining of the neoplastic cells.

SPECIMEN:

1. Right frontal brain lesion.
2. Right frontal brain lesion.

Printed by:
Printed on:

Page 1 of 4
(Continued)

[page 2 of 3]
AP Report

* Final Report *

TCGA-14-1821

CLINICAL HISTORY/OPERATIVE FINDINGS:

Right frontal craniotomy for tumor resection. Brain tumor. Right frontal brain lesion.

GROSS DESCRIPTION:

Two specimens are received.

Specimen #1 is received fresh for intraoperative consultation, labeled with the patient's name, hospital identification number and as "right frontal brain lesion." The specimen consists of tan irregular soft tissue fragments measuring 1.0 x 1.0 x 0.3 cm in aggregate dimension. Representative tissue is submitted for frozen section. A touch preparation smear was also made. The remainder of the cryostat block is entirely submitted in cassette "FS1A." The entire remaining tissue is submitted in cassette "1B."

Specimen #2 is received in formalin, labeled "right frontal brain lesion." The specimen consists of multiple tan irregular soft tissue fragments measuring 2.4 x 2.0 x 0.4 cm in aggregate dimension. The tissue is entirely submitted in cassette "2A."

INTRAOPERATIVE CONSULTATION:

FS1A, TP1A: RIGHT FRONTAL BRAIN LESION (FROZEN SECTION, TOUCH PREPARATION):
SMALL CELL MALIGNANCY, FAVOR GLIOBLASTOMA.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Page 1 (Continued...)

Printed by:
Printed on:

Page 2 of 4
(Continued)

[page 3 of 3]
AP Report

* Final Report *

TCGA-14-1821

Patient:

Accession Number:

Patient Number:

SPECIAL STAINS:

CHROMOGRAN	DONE
GFAP	DONE
SYNAP	DONE
KI-67	DONE
NF	DONE

Printed by:
Printed on:

Page 3 of 4
(Continued)

Source: NCI Genomic Data Commons file 6928138b-ee1c-44ea-ba8d-ca73dfba5c12 (TCGA-14-1821.2810E1D6-7F97-4D77-954A-F0B5FCF90D5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).